Somatic mutation profile of tumor specimen BA3040D (aliquot aq-BA3040D) from BEATAML1.0 case 2183, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.9 years (25,535 days).
Specimen BA3040D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96f5d16e-6f5f-4a3a-a643-5129d436f730.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2253D (Solid Tissue Normal), aliquot aq-BA2253D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8970eeaf-0e6b-4eae-97b0-32b7bf61a1d6

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Splice Site 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 84/184 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.337T>G p.F113V | Missense Mutation (SNP) | VAF 45/114 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781642, COSV52677695, COSV53351693; ClinVar: uncertain significance; called by muse, varscan2
- ADAMTS15 | c.2701G>A p.A901T | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs568020707; called by muse, mutect2, varscan2
- C11orf49 | c.821+2dup p.X274_splice | Splice Site (INS) | VAF 47/127 reads (37%) | catalogued as rs34737621; called by mutect2, pindel, varscan2
- C11orf95 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58311346; called by muse, mutect2
- DCSTAMP | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs961842159; called by muse, mutect2, varscan2
- FRMPD3 | c.3039del p.S1014Afs*18 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as rs752351689; called by mutect2, pindel
- PCDH15 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV100229874, COSV57382459; called by muse, varscan2
- ABCC10 | c.1448C>A p.A483D (on ENST00000372530 / NM_001198934.2; = p.A440D on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- CELSR2 | c.8140C>A p.H2714N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- DCAF7 | c.12C>A p.H4Q | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- IGHMBP2 | c.2133C>A p.S711R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- MAFB | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MNT | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- PLD1 | c.3219G>T p.W1073C | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD13B | c.1443G>A p.A481= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV61470180; called by muse, mutect2, varscan2
- GJA10 | c.1233C>T p.G411= | Silent (SNP) | VAF 37/48 reads (77%) | called by muse, mutect2, varscan2
- PLOD2 | c.54C>T p.H18= | Silent (SNP) | VAF 63/150 reads (42%) | catalogued as rs779227000; called by muse, mutect2, varscan2
- SHOX | c.699G>A p.A233= | Silent (SNP) | VAF 50/107 reads (47%) | called by muse, mutect2, varscan2
- UPK3BL2 | c.138G>A p.V46= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1375676026; called by mutect2, varscan2
- GOLGA6L10 | c.*32_*33del | 3'UTR (DEL) | VAF 16/135 reads (12%) | catalogued as rs1491273508; called by pindel, varscan2
